Somatic mutation profile of tumor specimen TCGA-CZ-5460-01A (aliquot TCGA-CZ-5460-01A-01D-1501-10) from TCGA case TCGA-CZ-5460, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 55.8 years (20,392 days).
Specimen TCGA-CZ-5460-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b40b770-3ddb-4bf3-81ab-5cdda9f4eb57.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-5460-11A (Solid Tissue Normal), aliquot TCGA-CZ-5460-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ff53d0b-9f27-4d06-af74-dff2216496b4

The open-access MAF lists 42 somatic variants for this specimen: 31 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 9, Frame Shift Ins 3, RNA 2, Nonsense Mutation 2, Frame Shift Del 2, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.586A>T p.K196* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | catalogued as rs281860296, CM093524, CM137225, COSV56543590; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.4146G>T p.W1382C | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as CM045654, COSV66069764; called by muse, mutect2, varscan2
- ANKRD1 | c.189G>T p.E63D | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV63311175; called by muse, mutect2, varscan2
- DUOX1 | c.1756G>A p.D586N | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as COSV58485663; called by muse, mutect2, varscan2
- FHOD3 | c.1835A>T p.K612I (on ENST00000359247 / NM_001281739.3; = p.K629I on NM_025135.5) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV99939543; called by muse, varscan2
- FRMPD1 | c.2584A>T p.S862C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as COSV66702366; called by muse, mutect2, varscan2
- G3BP1 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.541); catalogued as COSV62366846; called by muse, mutect2, varscan2
- GDPD1 | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 92/289 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs1209531842, COSV52384166; called by muse, mutect2, varscan2
- GJA10 | c.536A>G p.Y179C | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65356000; called by muse, mutect2, varscan2
- GOLGA4 | c.1189C>A p.Q397K | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.643); catalogued as COSV62713314; called by muse, mutect2, varscan2
- IL18RAP | c.1712A>G p.Q571R | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV51828666; called by muse, mutect2
- KMT2C | c.1299+1G>A p.X433_splice | Splice Site (SNP) | VAF 36/143 reads (25%) | catalogued as COSV51490994; called by muse, mutect2, varscan2
- NUDT7 | c.359T>G p.L120W | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as COSV51746905; called by muse, mutect2
- PKN2 | c.596A>T p.Q199L | Missense Mutation (SNP) | VAF 73/178 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV60134768; called by muse, mutect2, varscan2
- PRUNE2 | c.740T>C p.V247A | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV65029127; called by muse, mutect2, varscan2
- PRUNE2 | c.739G>C p.V247L | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.532); catalogued as COSV65026399, COSV65029134; called by muse, mutect2, varscan2
- PTPRR | c.1934G>A p.C645Y | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.667); catalogued as COSV51744956; called by muse, mutect2, varscan2
- SFMBT2 | c.1941A>T p.E647D | Missense Mutation (SNP) | VAF 72/297 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (0.97); catalogued as COSV62815301; called by muse, mutect2, varscan2
- SFMBT2 | c.1940A>C p.E647A | Missense Mutation (SNP) | VAF 71/298 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV62809227, COSV62815305; called by muse, mutect2, varscan2
- SLC16A4 | c.685T>A p.C229S | Missense Mutation (SNP) | VAF 31/298 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV63917224; called by muse, mutect2, varscan2
- ZMPSTE24 | c.148C>T p.H50Y | Missense Mutation (SNP) | VAF 64/300 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV65640082; called by muse, mutect2, varscan2
- ZNF287 | c.1354T>A p.Y452N | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67689028; called by muse, mutect2, varscan2
- AHR | c.1999dup p.Q667Pfs*7 | Frame Shift Ins (INS) | VAF 24/85 reads (28%) | called by mutect2, pindel, varscan2
- ARID2 | c.3821del p.G1274Efs*21 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | called by mutect2, pindel, varscan2
- OR8D2 | c.152T>A p.L51H | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.43); called by muse, varscan2
- PBRM1 | c.4676_4677dup p.Q1560Nfs*37 (on ENST00000296302 / NM_001366071.2; = p.Q1453Nfs*37 on NM_018313.5) | Frame Shift Ins (INS) | VAF 19/42 reads (45%) | called by mutect2, pindel, varscan2
- RNF213 | c.13555C>T p.P4519S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- SERPINA10 | c.371_373del p.I124del | In Frame Del (DEL) | VAF 6/15 reads (40%) | called by mutect2, varscan2
- SETD2 | c.5064_5066del p.Y1688_L1689delins* | Nonsense Mutation (DEL) | VAF 30/65 reads (46%) | called by mutect2, pindel, varscan2
- TAX1BP1 | c.1859dup p.N620Kfs*18 | Frame Shift Ins (INS) | VAF 42/134 reads (31%) | called by mutect2, varscan2
- ZNF100 | c.1147del p.Y383Tfs*67 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | called by mutect2, pindel, varscan2
- AGA | c.648A>T p.G216= | Silent (SNP) | VAF 80/380 reads (21%) | catalogued as COSV52807431; called by muse, varscan2
- B3GNT8 | c.105C>T p.Y35= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs199803357, COSV54199328; called by muse, mutect2, varscan2
- CWC27 | c.531G>A p.R177= | Silent (SNP) | VAF 82/231 reads (35%) | catalogued as rs755125562, COSV66888334; called by muse, mutect2, varscan2
- OSGEP | c.708T>C p.T236= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV52833587; called by muse, mutect2, varscan2
- PDPR | c.1908T>C p.S636= | Silent (SNP) | VAF 48/166 reads (29%) | catalogued as COSV55355775; called by muse, mutect2, varscan2
- PYGO1 | c.489T>C p.N163= | Silent (SNP) | VAF 51/160 reads (32%) | catalogued as COSV57349785; called by muse, mutect2
- RIN1 | c.705C>T p.P235= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100254271; called by muse, varscan2
- SPTBN2 | c.4065G>T p.S1355= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV59459885; called by muse, mutect2
- TAS2R50 | c.876G>A p.L292= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV67861804, COSV99061967; called by muse, mutect2, varscan2
- MAGEA5 | n.267C>A | RNA (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- OR2W5 | n.1241G>A | RNA (SNP) | VAF 8/15 reads (53%) | called by muse, mutect2
